FM case AD9009 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/611381cc-abd1-4597-9237-0406b287f910

Male, 73.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the other ill-defined sites. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
